Surgical pathology report (de-identified scan), TCGA case TCGA-B8-A8YJ, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site UNC, specimen TCGA-B8-A8YJ-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Kidney, right, robotic partial nephrectomy

ICD O.3

Procedure: partial nephrectomy

*Carcinoma, clear cell 8310/3
Site R Kidney NOS C64.9
JW 4/13/14*

Laterality: right

Histologic tumor type/subtype: renal cell carcinoma, clear cell type

Sarcomatoid features: not identified

Histologic grade (if applicable): Fuhrman nuclear grade 2

Tumor size (greatest dimension): 4.4 cm (gross measurement)

Tumor focality: unifocal

Extent of tumor invasion (if present specify if macroscopic or microscopic):

Capsular invasion/perirenal adipose tissue: not identified

Gerota's fascia: not present in specimen

Renal sinus: not present in specimen

Major veins (renal vein or segmental branches, IVC): not present in specimen

Ureter: not present in specimen

Venous (large vessel): not present in specimen

Lymphatic (small vessel): not identified

Histologic assessment of surgical margins:

Renal parenchymal margin (partial nephrectomy only): free of tumor

Renal capsular margin (partial nephrectomy only): free of tumor

Paranephric adipose tissue margin (partial nephrectomy only): free of tumor

Adrenal gland: not present in specimen

Lymph nodes: none submitted

Pathologic findings in non-neoplastic kidney: none

[page 2 of 2]
AJCC Staging:

pT1b

pNx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:

-year-old female with a right renal mass.

Gross Description:

Received is one appropriately labeled container, additionally labeled "right renal mass." It holds a 47.8 gram aggregate in total, 25 gram, 4.8 x 4.5 x 2.5 cm resection of kidney and separate lobulated, focally cauterized fat. The identified renal capsule is inked black, and the exposed parenchymal margin is inked blue. Sectioning demonstrates a 4.4 x 3.2 x 2.5 cm well circumscribed hemorrhagic cortical nodule with bright orange borders. This nodule comes within 0.1 cm of multiple blue inked parenchymal margins, expands the capsule, and comes within less than 0.1 cm of multiple black inked capsular margins. There is a compressed rim of gray/tan kidney tissue present. Tumor and normal is given to tissue procurement. Representative sections are submitted in blocks A1-A7 and representative sections from the aggregate of fat are submitted in block A8. Tissue remains in formalin.

Source: NCI Genomic Data Commons file 5fc202c2-c834-4bbc-810f-dc885b1179cf (TCGA-B8-A8YJ.D59DB2BD-7E9E-425C-900C-5FC3D34C827D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).